Somatic mutation profile of tumor specimen TCGA-JY-A6FG-01A (aliquot TCGA-JY-A6FG-01A-11D-A33E-09) from TCGA case TCGA-JY-A6FG, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 50.2 years (18,348 days).
Specimen TCGA-JY-A6FG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96516eeb-567b-4328-9e88-e5085a2e76ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A6FG-10A (Blood Derived Normal), aliquot TCGA-JY-A6FG-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca2a86f4-1ceb-4c00-b013-dd4981dc549a

The open-access MAF lists 243 somatic variants for this specimen: 175 protein-altering or splice-affecting, 56 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 149, Silent 56, Frame Shift Del 7, Nonsense Mutation 7, Frame Shift Ins 5, Splice Site 4, Intron 4, RNA 4, In Frame Del 2, 3'Flank 2, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 28/63 reads (44%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RHOA | c.101A>G p.Y34C | Missense Mutation (SNP) | VAF 13/58 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV69041520, COSV69042084; called by muse, mutect2, varscan2
- SMARCA4 | c.3574C>T p.R1192C | Missense Mutation (SNP) | VAF 19/40 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568509370, COSV60787617, COSV60789344; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMPD1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as rs200763423, CM041853, CM130660, COSV54968421; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TYR | c.1146C>A p.N382K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs104894315, CM100979, CM920696; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA10 | c.93dup p.Y32Ifs*3 | Frame Shift Ins (INS) | VAF 38/102 reads (37%) | catalogued as rs760530642; called by mutect2, varscan2
- ADAR | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs748161184, COSV99426565; called by muse, mutect2, varscan2
- ADCY9 | c.3028G>A p.G1010R | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53573573; called by muse, mutect2, varscan2
- AHCTF1 | c.4530G>T p.E1510D (on ENST00000366508; = p.E1484D on NM_015446.5) | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV100403014; called by muse, mutect2, varscan2
- ARMH4 | c.2302G>T p.D768Y | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50777035; called by muse, mutect2, varscan2
- ATCAY | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs372708763; called by muse, mutect2, varscan2
- BNIP5 | c.1419C>A p.S473R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as COSV101465133; called by muse, mutect2, varscan2
- BRPF1 | c.3329G>A p.R1110Q | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as rs777944933, COSV57351123; called by muse, mutect2, varscan2
- CACNA2D3 | c.1318C>T p.R440W | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs762550479, COSV99871175; called by muse, mutect2, varscan2
- CFTR | c.2928C>A p.F976L | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs776948957, COSV50048478; called by muse, mutect2, varscan2
- CORO2B | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274829318, COSV55950034; called by muse, mutect2, varscan2
- CRACR2A | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1334220004; called by muse, mutect2
- CRYBB3 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.776); catalogued as rs373833533, COSV99309241; called by muse, mutect2, varscan2
- CSMD3 | c.4711G>A p.V1571I (on ENST00000297405 / NM_001363185.1; = p.V1467I on NM_052900.3) | Missense Mutation (SNP) | VAF 32/161 reads (20%) | SIFT tolerated (1); PolyPhen possibly damaging (0.858); catalogued as COSV52316458; called by muse, mutect2, varscan2
- CX3CR1 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.537); catalogued as rs768761417; called by muse, mutect2, varscan2
- CXXC5 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV56794351; called by muse, mutect2, varscan2
- DCANP1 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 17/42 reads (40%) | catalogued as rs867684751; called by muse, mutect2, varscan2
- DNAJC1 | c.734C>A p.A245D | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV65411840; called by muse, mutect2
- DTX3L | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755071547, COSV56144163; called by muse, mutect2, varscan2
- DYRK1A | c.30C>A p.C10* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | catalogued as rs1555976936; called by muse, mutect2, varscan2
- EPB41 | c.1636+1G>A p.X546_splice (on ENST00000343067 / NM_001166005.2; = p.X337_splice on NM_004437.4) | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as COSV58054742; called by muse, mutect2, varscan2
- FBXO34 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 37/62 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs767666103; called by muse, mutect2, varscan2
- FBXO40 | c.1010G>T p.G337V | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57525860; called by muse, mutect2, varscan2
- FLT1 | c.2878G>A p.V960I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs554058758, COSV56725597; called by muse, mutect2, varscan2
- FLVCR1 | c.1413G>A p.Q471= | Splice Region (SNP) | VAF 16/49 reads (33%) | catalogued as rs1391075754; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPAA1 | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs782229443; called by muse, mutect2, varscan2
- IQCE | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as rs774866500; called by muse, mutect2, varscan2
- ITK | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV70060465; called by muse, mutect2, varscan2
- KALRN | c.6728G>A p.R2243Q (on ENST00000360013 / NM_001024660.4; = p.R546Q on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.219); catalogued as rs374234847; called by muse, mutect2, varscan2
- KAT14 | c.2116G>A p.V706I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs369048963, COSV66607593; called by muse, varscan2
- KCNH4 | c.2321C>T p.S774F | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV52918431; called by muse, mutect2, varscan2
- KIAA0408 | c.1778C>A p.S593Y | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.525); catalogued as COSV64107487; called by muse, mutect2, varscan2
- KIF6 | c.1638G>T p.K546N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV54688443; called by muse, mutect2, varscan2
- KLHDC7A | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs919807320, COSV101272824; called by muse, mutect2, varscan2
- LNX1 | c.1196G>A p.R399H (on ENST00000263925 / NM_001126328.3; = p.R303H on NM_032622.2) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs769520904; called by muse, mutect2, varscan2
- LRRC43 | c.1024G>A p.V342M | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756689259; called by muse, mutect2, varscan2
- LRRC56 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as rs775139825; called by muse, mutect2, varscan2
- LRRN1 | c.109G>A p.V37I | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs375458276; called by muse, mutect2, varscan2
- LSS | c.1348G>A p.G450S | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs375698498; called by muse, mutect2, varscan2
- MTMR4 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329857367, COSV60199263; called by muse, mutect2
- MUC16 | c.6296C>A p.S2099Y | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV101198404; called by muse, mutect2, varscan2
- NAV2 | c.2243G>A p.R748Q (on ENST00000396087 / NM_001244963.2; = p.R725Q on NM_145117.5) | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769722553; called by muse, mutect2, varscan2
- NCAPD3 | c.1439C>T p.S480L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as rs201688313; called by muse, mutect2, varscan2
- PCDH11X | c.3742C>A p.P1248T | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100016706, COSV53467958; called by muse, mutect2, varscan2
- PCDHA7 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV65346741; called by muse, mutect2, varscan2
- PHACTR2 | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1357264620; called by muse, mutect2, varscan2
- PIF1 | c.1801G>A p.V601I | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs766453021; called by muse, mutect2, varscan2
- PPP1R13B | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs776014974, COSV52455795; called by muse, mutect2, varscan2
- PRLHR | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs1034624604; called by muse, mutect2, varscan2
- PWP1 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as rs781659412, COSV69833023; called by muse, mutect2, varscan2
- RGS8 | c.227C>T p.T76M (on ENST00000367556 / NM_001369564.2; = p.T94M on NM_033345.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs759655284, COSV99276455; called by muse, varscan2
- RHO | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56213164; called by muse, mutect2, varscan2
- SLC19A3 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51452985; called by muse, mutect2, varscan2
- SLC39A7 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1194338913; called by muse, mutect2, varscan2
- SMG8 | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV56286269; called by muse, mutect2, varscan2
- SMIM21 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs745449933; called by muse, mutect2, varscan2
- SPAG17 | c.6193G>T p.A2065S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.368); catalogued as rs1557850614; called by muse, mutect2, varscan2
- SPOPL | c.310T>A p.F104I | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV104381335; called by muse, mutect2, varscan2
- TBC1D31 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.521); catalogued as rs1271522641, COSV99783322; called by muse, mutect2, varscan2
- TGFBR1 | c.1121G>A p.G374E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1554701930, CM064322, COSV66624856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM101 | c.20C>A p.S7* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as rs894531067; called by muse, mutect2, varscan2
- TMEM161A | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.242); catalogued as rs1460036282, COSV99365477; called by muse, mutect2, varscan2
- TRIB3 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as rs371072439; called by muse, mutect2
- TSLP | c.380G>T p.R127M | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV61292037; called by muse, mutect2, varscan2
- UBR3 | c.3452G>A p.R1151H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs748028932, COSV55847157; called by muse, mutect2, varscan2
- UTRN | c.9304C>T p.R3102* | Nonsense Mutation (SNP) | VAF 44/92 reads (48%) | catalogued as COSV62305791; called by muse, mutect2, varscan2
- WIPF1 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV55811568; called by muse, mutect2, varscan2
- ZNF320 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV67088780; called by muse, mutect2, varscan2
- ZNF626 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs782429235, COSV74130597; called by muse, mutect2, varscan2
- ABCC8 | c.3974A>C p.Y1325S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ACACA | c.5131G>A p.G1711S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.6404G>C p.G2135A | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANXA4 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by mutect2, varscan2
- ARHGAP29 | c.686dup p.L230Afs*2 | Frame Shift Ins (INS) | VAF 17/59 reads (29%) | called by mutect2, varscan2
- BMX | c.970T>A p.S324T | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- C17orf80 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- CACNA1C | c.2319G>T p.K773N | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CCDC180 | c.1866del p.K622Nfs*2 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- CCDC93 | c.1292A>T p.E431V | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDC20B | c.282_289del p.Q94Hfs*16 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | called by mutect2, pindel, varscan2
- CEP192 | c.2885A>G p.N962S | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CFAP300 | c.524G>A p.C175Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CHD6 | c.7628C>A p.A2543E | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CLEC16A | c.1262A>C p.E421A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- COL11A1 | c.4399C>G p.Q1467E | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CRPPA | c.1231C>A p.L411I (on ENST00000407010 / NM_001368197.1; = p.L361I on NM_001101417.4) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CSDE1 | c.1592_1595dup p.F532Lfs*4 (on ENST00000358528 / NM_001007553.3; = p.F501Lfs*4 on NM_007158.6) | Frame Shift Ins (INS) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- CSMD3 | c.4910C>G p.P1637R (on ENST00000297405 / NM_001363185.1; = p.P1533R on NM_052900.3) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- CSNK1E | c.1119G>T p.E373D | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CTDSPL | c.314G>A p.G105E (on ENST00000273179 / NM_001008392.2; = p.G94E on NM_005808.3) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- DCAF4L1 | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- DCLK3 | c.1087G>T p.G363W | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DENND4B | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- DEPTOR | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2
- DNAH17 | c.12766C>G p.L4256V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DOP1A | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- E2F7 | c.2020_2021del p.L674Cfs*4 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by pindel, varscan2
- EIF3G | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELF2 | c.1135G>A p.V379M (on ENST00000379550 / NM_001331036.2; = p.V319M on NM_006874.4) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- ERN2 | c.883A>C p.T295P | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- F5 | c.1467G>T p.E489D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FIGN | c.210dup p.Y71Ifs*35 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | called by mutect2, varscan2
- FLG | c.8521_8523del p.T2841del | In Frame Del (DEL) | VAF 27/150 reads (18%) | called by pindel, varscan2
- FLNC | c.5806C>A p.H1936N | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- FZD1 | c.1668C>A p.F556L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- FZD6 | c.1606A>G p.K536E | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- GLI1 | c.773G>A p.S258N | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR149 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GRAMD2A | c.676C>G p.P226A | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- GTF3C2 | c.2127+2T>C p.X709_splice | Splice Site (SNP) | VAF 14/46 reads (30%) | called by muse, mutect2, varscan2
- H4C5 | c.119G>C p.R40P | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HBP1 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- HERC2 | c.8095G>C p.V2699L | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- HSP90AB1 | c.569_572del p.T190Sfs*3 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by pindel, varscan2
- IFT140 | c.1652+2T>C p.X551_splice | Splice Site (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- IGF1 | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV7-81 | c.241C>A p.Q81K | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- KDM1A | c.508dup p.E170Gfs*17 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- KIAA1586 | c.1637G>A p.R546K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIR3DL2 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 64/192 reads (33%) | SIFT tolerated (0.97); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- LRRCC1 | c.86T>G p.M29R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- LRRK2 | c.3466G>C p.E1156Q | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MDC1 | c.4698G>C p.K1566N | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- MERTK | c.2653G>T p.A885S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- MRPS25 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MTREX | c.3055C>G p.L1019V | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MUC13 | c.1510C>T p.H504Y | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- MYH7 | c.2616G>T p.E872D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- N4BP2 | c.4852G>A p.D1618N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NCAM2 | c.1147G>T p.A383S | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- NDST3 | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- NEK4 | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- NFATC4 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PALD1 | c.755_757del p.E252del | In Frame Del (DEL) | VAF 8/28 reads (29%) | called by pindel, varscan2
- PAX4 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH15 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- PCDHB13 | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- PHIP | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- PKP1 | c.2063_2069del p.I688Tfs*45 | Frame Shift Del (DEL) | VAF 13/22 reads (59%) | called by mutect2, pindel, varscan2
- PPFIBP2 | c.1669C>A p.Q557K | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PRPF8 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRR12 | c.1759C>A p.P587T (on ENST00000615927; = p.P1408T on NM_020719.3) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRTG | c.1981C>T p.Q661* | Nonsense Mutation (SNP) | VAF 24/68 reads (35%) | called by muse, mutect2, varscan2
- PTN | c.376C>A p.L126M | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PWWP2B | c.215A>T p.E72V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- PXDNL | c.1058C>A p.A353D | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RGS22 | c.1382T>C p.L461P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SENP8 | c.636G>T p.K212N | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- SHROOM2 | c.3715C>T p.P1239S | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SI | c.3595G>T p.G1199C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIX6 | c.46G>T p.G16W | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SLC24A1 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D5 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- TENM2 | c.8153G>A p.G2718E (on ENST00000518659 / NM_001122679.2; = p.G2479E on NM_001080428.3) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, varscan2
- TENM4 | c.7984C>A p.R2662S | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TFAP2A | c.929G>T p.C310F (on ENST00000482890; = p.C302F on NM_001032280.3) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- TMA7 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TPH1 | c.4A>T p.I2F | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- TUBB | c.147_148del p.Y50Lfs*3 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | called by pindel, varscan2
- TULP3 | c.27T>G p.S9R | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- USP28 | c.934A>G p.T312A | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- USP31 | c.1951-2A>C p.X651_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- UTP23 | c.22C>T p.H8Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- VCAN | c.2453C>A p.T818K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZNF251 | c.1096C>G p.Q366E | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF714 | c.993_994del p.H331Qfs*13 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel*, varscan2
- ZSWIM5 | c.3432G>T p.K1144N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZUP1 | c.476G>C p.C159S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AFDN | c.2910C>T p.H970= | Silent (SNP) | VAF 18/46 reads (39%) | called by muse, mutect2, varscan2
- AL662899.2 | c.390G>A p.T130= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs924292776; called by muse, mutect2, varscan2
- ALMS1 | c.4116C>A p.G1372= | Silent (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.861G>A p.S287= | Silent (SNP) | VAF 36/99 reads (36%) | catalogued as rs879628150; called by muse, mutect2, varscan2
- ATF7IP2 | c.1896T>A p.I632= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs558578447; called by muse, mutect2, varscan2
- ATP5F1D | c.357C>A p.A119= | Silent (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- ATP9A | c.1158G>A p.S386= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs376405770; called by muse, mutect2, varscan2
- C12orf66 | c.381G>A p.E127= | Silent (SNP) | VAF 17/38 reads (45%) | called by muse, mutect2, varscan2
- CCDC80 | c.2685G>A p.S895= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs768070081, COSV99244323; called by muse, mutect2, varscan2
- CD244 | c.441C>T p.D147= (on ENST00000368033 / NM_001166663.2; = p.D142= on NM_016382.4) | Silent (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- CELSR1 | c.6129C>T p.V2043= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- DLGAP3 | c.2040C>T p.G680= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs774076646; called by muse, mutect2, varscan2
- E2F5 | c.564G>A p.L188= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- EFCAB14 | c.660G>A p.K220= | Silent (SNP) | VAF 8/56 reads (14%) | called by muse, mutect2, varscan2
- ELL | c.1539C>T p.Y513= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as rs199594269, COSV53212354; called by muse, mutect2, varscan2
- FAM83F | c.255C>A p.G85= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- FUT8 | c.1062C>T p.G354= (on ENST00000360689 / NM_001371534.1; = p.G191= on NM_004480.4) | Silent (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- GDA | c.432A>G p.T144= | Silent (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- GMEB2 | c.72C>T p.D24= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs775670456, COSV56606206; called by muse, mutect2, varscan2
- GRID1 | c.507C>T p.Y169= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs368572646; called by muse, mutect2, varscan2
- GRIK2 | c.36C>A p.V12= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- GUCY2F | c.2235C>T p.V745= | Silent (SNP) | VAF 22/25 reads (88%) | called by muse, varscan2
- HDX | c.678G>T p.G226= | Silent (SNP) | VAF 22/27 reads (81%) | called by muse, mutect2, varscan2
- HLA-DOA | c.450C>T p.N150= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs756316995, COSV57713460; called by muse, mutect2, varscan2
- HNF4A | c.1236C>T p.L412= | Silent (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- IFT80 | c.927A>G p.Q309= | Silent (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- KDM3A | c.3513A>T p.G1171= | Silent (SNP) | VAF 9/34 reads (26%) | called by muse, mutect2, varscan2
- LONP1 | c.2877G>A p.R959= | Silent (SNP) | VAF 30/43 reads (70%) | catalogued as rs150782036; called by muse, mutect2, varscan2
- LRP1B | c.7290G>A p.R2430= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- LRRK1 | c.5787C>T p.I1929= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as rs772136882, COSV99441140, COSV99443350; called by muse, mutect2, varscan2
- MAP3K4 | c.3276G>A p.A1092= | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs369504568; called by muse, mutect2, varscan2
- MKI67 | c.1953G>A p.S651= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs142241283; called by muse, mutect2, varscan2
- MOCOS | c.1722C>T p.V574= | Silent (SNP) | VAF 8/30 reads (27%) | called by muse, mutect2, varscan2
- MTUS2 | c.1443G>A p.T481= | Silent (SNP) | VAF 33/60 reads (55%) | catalogued as rs201515125; called by muse, mutect2, varscan2
- MYCBP2 | c.10869A>C p.S3623= (on ENST00000357337; = p.S3661= on NM_015057.5) | Silent (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- NAALADL2 | c.1206G>A p.A402= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs772833242, COSV69158740; called by muse, mutect2, varscan2
- NECTIN1 | c.1041G>A p.R347= | Silent (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2
- NUP85 | c.57G>A p.K19= | Silent (SNP) | VAF 25/83 reads (30%) | called by muse, mutect2, varscan2
- PCNT | c.8448G>A p.L2816= | Silent (SNP) | VAF 19/35 reads (54%) | called by muse, mutect2, varscan2
- PHIP | c.2589G>T p.L863= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- POTEE | c.2625C>T p.T875= | Silent (SNP) | VAF 36/158 reads (23%) | called by muse, varscan2
- RDH13 | c.834G>A p.E278= (on ENST00000415061 / NM_001145971.2; = p.E207= on NM_138412.4) | Silent (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- RNPEPL1 | c.1080C>T p.F360= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs749766269; called by muse, mutect2, varscan2
- S1PR4 | c.378C>T p.F126= | Silent (SNP) | VAF 7/11 reads (64%) | called by muse, mutect2, varscan2
- SEMA3A | c.1917A>G p.L639= | Silent (SNP) | VAF 18/48 reads (38%) | called by muse, mutect2, varscan2
- SMC4 | c.1918C>T p.L640= | Silent (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- SREBF1 | c.2010C>T p.A670= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as rs776609977; called by muse, mutect2, varscan2
- ST6GALNAC6 | c.291C>A p.G97= | Silent (SNP) | VAF 18/52 reads (35%) | called by muse, mutect2, varscan2
- STK4 | c.153G>A p.E51= | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- THSD7B | c.2463C>A p.G821= | Silent (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- TRIO | c.2178C>T p.N726= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs762757315, COSV60081149; called by muse, mutect2, varscan2
- TSHZ3 | c.660C>T p.S220= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs779306559; called by muse, mutect2, varscan2
- VSIG10 | c.183G>A p.S61= | Silent (SNP) | VAF 45/89 reads (51%) | catalogued as rs117781232; called by muse, mutect2, varscan2
- VWF | c.3363G>A p.R1121= | Silent (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- WDR90 | c.2985C>A p.L995= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV99554304; called by muse, mutect2, varscan2
- ZNF180 | c.2037T>C p.H679= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs1482217130; called by muse, mutect2, varscan2
- AC073310.1 | n.259C>T | RNA (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- AOPEP | c.*5-1387C>G | Intron (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ASPH | c.323-11684G>A | Intron (SNP) | VAF 20/69 reads (29%) | catalogued as rs1228888052; called by muse, mutect2, varscan2
- ATG2A | chr11:64891363 C>T | 3'Flank (SNP) | VAF 16/42 reads (38%) | catalogued as rs754568320; called by muse, mutect2, varscan2
- FMN1 | c.2044-1511G>A | Intron (SNP) | VAF 5/64 reads (8%) | catalogued as COSV57925102; called by muse, mutect2
- IL15 | c.110+601G>T | Intron (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99650857; called by muse, mutect2, varscan2
- IL17A | c.-2C>T | 5'UTR (SNP) | VAF 24/74 reads (32%) | catalogued as rs763918114; called by muse, mutect2, varscan2
- LINC01098 | n.636G>T | RNA (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- MYADM | chr19:53874350 C>T | 3'Flank (SNP) | VAF 13/37 reads (35%) | catalogued as rs765254576, COSV100425039; called by muse, mutect2, varscan2
- SNORD3D | n.212A>G | RNA (SNP) | VAF 10/72 reads (14%) | catalogued as rs530227028; called by muse, varscan2
- TCP10L3 | n.350A>C | RNA (SNP) | VAF 12/42 reads (29%) | called by muse, mutect2, varscan2
- ZNF578 | chr19:52451237 C>T | 5'Flank (SNP) | VAF 30/67 reads (45%) | catalogued as COSV56521471; called by muse, mutect2, varscan2
